Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0WQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0WQ-01A (Primary Tumor).

[page 1 of 3]
IPDAA Discrepancy		
Re-review Initials	BB	Date Reviewed: 9/20/10

1CB-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1

Surgical Pathology Report

Patient Name:

Med Rec No:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

Pl. Phone no

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Pending pathology exam

Specimen(s) Received:

- A: Left pelvic lymph node biopsy
- B: Left periaortic lymph node biopsy
- C: Right pelvic lymph node biopsy
- D: Right periaortic lymph node biopsy
- E: Uterus, cervix, right tube and ovary

DIAGNOSIS:

- A. Left pelvic lymph node biopsy: 9 lymph nodes negative for metastasis (0/9)
- B. Left periaortic lymph node biopsy: 4 lymph nodes negative for metastasis (0/4)
- C. Right pelvic lymph node biopsy: 5 lymph nodes negative for metastasis (0/5)
- D. Right periaortic lymph node biopsy: 7 lymph nodes negative for metastasis (0/7)
- E. Uterus, cervix, right tube and ovary: ENDOMETRIAL ADENOCARCINOMA

Tumor information

Procedure

Histologic type:

Histologic grade:

Size:

Location:

Depth of myometrial invasion:

Lymphovascular invasion:

Invasion of contiguous structures:

Ovarian involvement:

Fallopian tube involvement:

Regional lymph nodes:

Pelvic:

Periaortic:

Total:

Peritoneal cytology:

TAH- RSO

Endometrioid carcinoma

Grade 1

5.0 cm

Posterior portion of uterine corpus

No myometrial invasion, tumor arises from an endometrial polyp

Absent

Absent

Absent

Absent

14 lymph nodes

11 lymph nodes

25 lymph node negative for metastasis

Negative (see report)

Regulatory Statement

This laboratory statement may be applicable to some of the tests performed and used in developing the above report. This has been developed and its performance characteristics have been determined or approved by the U.S. Food and Drug Administration. The FDA has determined that such statement is not necessary. This has been used for clinical diagnosis purposes. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Medical Director

Page 1 of 3

[page 2 of 3]
Surgical Pathology Report

Other:
Stage:

Multiple intramural leiomyomas
G1; pT1a pN0 pMX (stage IA if M0)

Gross Description

- A. Received in formalin labeled "1, LT pelvic lymph nodes" are multiple fragments of soft tan to yellow tissue, 8 gm, aggregating up to 4.3 x 4.0 x 1.3 cm. There are nine lymph nodes grossly identified, largest up to 2.0 x 0.5 x 0.4 cm (inked). Submitted in toto in three cassettes, with three lymph nodes in cassette A (largest lymph node inked blue, one unstained, one inked orange). Six lymph nodes in A2 and rest of specimen in A3.
- B. Received in formalin labeled "2, LT periaortic lymph node BX" are multiple fragments of soft tan to yellow tissue, 3 gm, aggregating up to 2.7 x 2.5 x 1.1 cm. There are three lymph nodes grossly identified, largest up to 1.0 x 0.5 x 0.4 cm (inked blue). Submitted in toto in two cassettes, with three lymph nodes in cassette B1 and rest of specimen in B2.
- C. Received in formalin labeled "RT pelvic lymph node" are multiple fragments of soft tan to yellow tissue, 7 gm, aggregating up to 4.2 x 4.0 x 1.1 cm. There are three lymph nodes grossly identified, largest up to 1.1 x 0.6 x 0.4 cm (inked blue). Submitted in toto in three cassettes, with three lymph nodes (largest inked blue) in cassette C1. Rest of specimen in C2 and C3.
- D. Received in formalin labeled "RT periaortic node BX" are two pieces of soft tan to yellow tissue, 2.0 gm, aggregating up to 4.1 x 1.3 x 0.4 cm. No lymph nodes are grossly identified. Submitted in toto in two cassettes.
- E. Received: In formalin are two pieces of unoriented, unopened soft tan to pink tissue
- | | |
|------------------------------------|--|
| Labeled: | Right tube and ovary, uterus and cervix |
| Weight: | 302 gm |
| Size: | |
| Uterus: | 13.6 x 9.2 x 8.5 cm |
| Right ovary: | 3.3 x 1.4 x 0.6 cm |
| Appearance | |
| Tumor | |
| Location: | Posterior portio of the uterus corpus |
| Size: | 5.0 x 1.5 x 1.5 cm |
| Appearance: | Smooth, tan to pink, polypoid with a friable base |
| Depth of invasion: | Superficial, appears to involve the upper half of the myometrium only |
| Invasion of contiguous structures: | None grossly identified |
| Distance from margins: | 2.5 cm from the cervical margin |
| Cervix: | Smooth, shiny, white with no lesions identified |
| Endometrium: | 0.2 cm, shiny, smooth, tan with areas of hemorrhage and mucoid material |
| Myometrium: | 2.9 cm. No areas of adenomyosis grossly identified. There are multiple well circumscribed white myomas, with white whirled cut surfaces. No areas of hemorrhage or calcification are identified within the myomas, largest up to 4.5 x 4.0 x 3.9 cm |
| Right tube and ovary: | The right tube measures 6.5 x 0.5 x 0.4 cm, is grossly unremarkable, with multiple paratubal cystic structures, largest up to 0.2 x 0.2 x 0.2 cm, filled with clear serous fluid. The ovary cut surface is white, homogeneous with no cystic structure grossly identified. |
| Lymph nodes: | None grossly identified. |
| Special studies: | Pending |
| Other: | None |

KEY TO CASSETTES:

- | | | |
|---------|---|---|
| E1 | - | Cervix |
| E2 | - | Upper endocervical canal, full thickness |
| E3-E10 | - | Tumor and underlying myometrium |
| E11 | - | Right and left parametrium (right parametrium inked black, left parametrium inked blue) |
| E12-E13 | - | Representative of myomas |
| E14 | - | Right adnexa |

Microscopic Description

A-E. The microscopic findings support the above diagnoses.

[page 3 of 3]
[REDACTED] **Surgical Pathology Report** [REDACTED]

Electronically Signed Out By [REDACTED]

Source: NCI Genomic Data Commons file 4a39557b-8554-470b-8a83-f0fc9718e0e2 (TCGA-BS-A0WQ.207B2565-ABB2-4F05-8B54-2280DAC57AD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).